Somatic mutation profile of tumor specimen MMRF_1847_1_BM_CD138pos (aliquot MMRF_1847_1_BM_CD138pos_T1_KBS5U_L05776) from MMRF case MMRF_1847, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 52.1 years (19,033 days).
Specimen MMRF_1847_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d8395594-19c5-460e-9b89-dcd9f9d6823a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1847_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1847_1_PB_Whole_C3_KBS5U_L05802; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c23731c2-43f3-44f0-a635-49d00fb508e0

The open-access MAF lists 111 somatic variants for this specimen: 41 protein-altering or splice-affecting, 17 silent, 53 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 35, 3'UTR 29, Intron 18, Silent 17, Nonsense Mutation 4, 5'UTR 3, 5'Flank 3, Splice Region 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA4 | c.42C>A p.N14K | Missense Mutation (SNP) | VAF 65/77 reads (84%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as CM161613; called by muse, mutect2, varscan2
- ACTG1 | c.98C>A p.S33Y | Missense Mutation (SNP) | VAF 95/219 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV59512263; called by muse, mutect2, varscan2
- ATN1 | c.2486_2503del p.R829_E834del | In Frame Del (DEL) | VAF 14/30 reads (47%) | catalogued as rs1367398901; called by mutect2, varscan2
- CHRNA9 | c.146T>C p.V49A | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.67); catalogued as COSV59574679; called by muse, mutect2
- CHTF18 | c.2476C>T p.R826C | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.037); catalogued as rs202088652; called by muse, mutect2, varscan2
- GALNT14 | c.1024G>A p.V342I | Missense Mutation (SNP) | VAF 43/154 reads (28%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as rs374361605; called by muse, mutect2, varscan2
- HELZ2 | c.6638G>A p.G2213D (on ENST00000467148 / NM_001037335.2; = p.G1644D on NM_033405.3) | Missense Mutation (SNP) | VAF 50/112 reads (45%) | SIFT tolerated (0.26); PolyPhen benign (0.108); catalogued as rs761861801; called by muse, mutect2, varscan2
- IGHV1-24 | c.337T>C p.Y113H | Missense Mutation (SNP) | VAF 97/163 reads (60%) | SIFT deleterious (0); PolyPhen possibly damaging (0.632); catalogued as rs150510876; called by muse, mutect2, varscan2
- IGHV1-24 | c.230C>T p.T77I | Missense Mutation (SNP) | VAF 224/340 reads (66%) | SIFT deleterious (0.03); PolyPhen benign (0.061); catalogued as rs529857833; called by muse, varscan2
- IGHV2-70 | c.287A>G p.K96R | Missense Mutation (SNP) | VAF 88/147 reads (60%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.579); catalogued as rs138836314; called by muse, varscan2
- MDGA1 | c.430C>T p.R144* | Nonsense Mutation (SNP) | VAF 26/51 reads (51%) | catalogued as rs1449487161, COSV99776398; called by muse, mutect2, varscan2
- PLA2G4E | c.1927C>T p.R643* | Nonsense Mutation (SNP) | VAF 75/137 reads (55%) | catalogued as rs776075882; called by muse, mutect2, varscan2
- TEX55 | c.178C>G p.P60A | Missense Mutation (SNP) | VAF 34/236 reads (14%) | SIFT tolerated (0.66); PolyPhen benign (0.157); catalogued as COSV55211478, COSV99817680; called by muse, mutect2, varscan2
- TGM7 | c.646C>T p.R216W | Missense Mutation (SNP) | VAF 37/285 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.07); catalogued as rs550814720, COSV101476917; called by muse, mutect2, varscan2
- VWA3B | c.1180C>A p.L394M | Missense Mutation (SNP) | VAF 59/121 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV68242126; called by muse, mutect2, varscan2
- ZNF469 | c.10670G>A p.G3557D (on ENST00000437464; = p.G3585D on NM_001367624.2) | Missense Mutation (SNP) | VAF 57/122 reads (47%) | SIFT tolerated (0.09); PolyPhen benign (0.422); catalogued as rs1320901091; called by muse, mutect2, varscan2
- ARL4A | c.158G>C p.G53A | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.192); called by muse, mutect2, varscan2
- ARSL | c.1757A>T p.D586V | Missense Mutation (SNP) | VAF 28/92 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.14); called by muse, mutect2, varscan2
- CADPS | c.957C>A p.D319E | Missense Mutation (SNP) | VAF 23/71 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.012); called by mutect2, varscan2
- CARD16 | c.107A>C p.N36T | Missense Mutation (SNP) | VAF 21/481 reads (4%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.843); called by muse, mutect2
- CEP85 | c.1496T>G p.L499R | Missense Mutation (SNP) | VAF 24/73 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- CFAP91 | c.197G>A p.R66K | Missense Mutation (SNP) | VAF 10/206 reads (5%) | SIFT tolerated (0.25); PolyPhen benign (0.001); called by muse, mutect2
- DMRTA1 | c.1088T>G p.V363G | Missense Mutation (SNP) | VAF 10/148 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); called by muse, mutect2
- ELF1 | c.1529G>C p.S510T | Missense Mutation (SNP) | VAF 48/49 reads (98%) | SIFT tolerated (0.56); PolyPhen benign (0.248); called by muse, mutect2, varscan2
- FAM171A2 | c.1993C>T p.Q665* | Nonsense Mutation (SNP) | VAF 59/120 reads (49%) | called by muse, varscan2
- FAM234A | c.860G>T p.C287F | Missense Mutation (SNP) | VAF 44/91 reads (48%) | SIFT tolerated (0.49); PolyPhen benign (0); called by muse, mutect2, varscan2
- FRMD4B | c.2355G>T p.K785N | Missense Mutation (SNP) | VAF 42/79 reads (53%) | SIFT tolerated (0.29); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- GCNT4 | c.1214G>A p.G405E | Missense Mutation (SNP) | VAF 90/220 reads (41%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- GPC3 | c.1646T>C p.I549T | Missense Mutation (SNP) | VAF 28/29 reads (97%) | SIFT tolerated (0.12); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- IGHV1-69D | c.234C>G p.N78K | Missense Mutation (SNP) | VAF 73/241 reads (30%) | SIFT tolerated (0.66); PolyPhen benign (0.003); called by muse, varscan2
- IGHV1-69D | c.150C>G p.S50R | Missense Mutation (SNP) | VAF 50/171 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.012); called by muse, varscan2
- IGLC2 | c.167C>G p.T56S | Missense Mutation (SNP) | VAF 18/32 reads (56%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.125); called by muse, varscan2
- IGLV3-25 | c.16C>G p.L6V | Missense Mutation (SNP) | VAF 50/126 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.316); called by muse, mutect2, varscan2
- OR8J3 | c.163C>T p.L55F | Missense Mutation (SNP) | VAF 55/154 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PARP8 | c.776G>T p.S259I | Missense Mutation (SNP) | VAF 120/274 reads (44%) | SIFT tolerated (0.42); PolyPhen benign (0.261); called by muse, mutect2, varscan2
- PHYHIPL | c.596+5G>T | Splice Region (SNP) | VAF 12/24 reads (50%) | called by muse, mutect2
- PNISR | c.1267C>T p.Q423* | Nonsense Mutation (SNP) | VAF 8/150 reads (5%) | called by muse, mutect2
- SLC4A1 | c.1484T>G p.F495C | Missense Mutation (SNP) | VAF 86/190 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- SOX11 | c.1178C>T p.S393L | Missense Mutation (SNP) | VAF 74/148 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.543); called by muse, mutect2, varscan2
- UBOX5 | c.589C>T p.P197S | Missense Mutation (SNP) | VAF 3/44 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- WDR38 | c.145G>C p.E49Q | Missense Mutation (SNP) | VAF 9/117 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.19); called by muse, mutect2
- CACNA1H | c.3543C>T p.D1181= | Silent (SNP) | VAF 62/119 reads (52%) | catalogued as rs958144782, COSV61987153; called by muse, mutect2, varscan2
- FOXA2 | c.210C>T p.G70= (on ENST00000377115 / NM_153675.3; = p.G76= on NM_021784.5) | Silent (SNP) | VAF 21/51 reads (41%) | catalogued as COSV101008303; called by muse, mutect2, varscan2
- GPR4 | c.549C>G p.L183= | Silent (SNP) | VAF 48/162 reads (30%) | called by muse, mutect2, varscan2
- IGHV1-24 | c.135A>G p.G45= | Silent (SNP) | VAF 164/271 reads (61%) | catalogued as rs530036379; called by muse, varscan2
- IGHV2-70D | c.60G>A p.Q20= | Silent (SNP) | VAF 99/155 reads (64%) | called by muse, varscan2
- IGLC2 | c.252C>T p.S84= | Silent (SNP) | VAF 46/96 reads (48%) | called by muse, varscan2
- IRF2BP1 | c.483G>A p.L161= | Silent (SNP) | VAF 32/80 reads (40%) | called by muse, mutect2, varscan2
- IRS1 | c.1608C>T p.H536= | Silent (SNP) | VAF 44/93 reads (47%) | called by muse, mutect2, varscan2
- ITGAX | c.393C>A p.P131= | Silent (SNP) | VAF 36/60 reads (60%) | called by muse, mutect2, varscan2
- L1CAM | c.2655G>A p.L885= | Silent (SNP) | VAF 7/60 reads (12%) | called by muse, mutect2, varscan2
- MROH2B | c.2970T>G p.S990= | Silent (SNP) | VAF 115/241 reads (48%) | called by muse, mutect2, varscan2
- OR4X1 | c.21G>A p.V7= | Silent (SNP) | VAF 36/91 reads (40%) | catalogued as COSV60723373; called by muse, mutect2, varscan2
- OR52A1 | c.384C>A p.I128= | Silent (SNP) | VAF 31/73 reads (42%) | called by muse, mutect2, varscan2
- POU3F3 | c.354G>A p.A118= | Silent (SNP) | VAF 11/19 reads (58%) | called by muse, mutect2
- RGS7BP | c.57G>A p.S19= | Silent (SNP) | VAF 34/72 reads (47%) | catalogued as rs1220869861; called by muse, mutect2, varscan2
- RNF145 | c.1434C>T p.I478= (on ENST00000424310 / NM_001199383.2; = p.I506= on NM_144726.2) | Silent (SNP) | VAF 18/44 reads (41%) | catalogued as rs755516595; called by muse, mutect2, varscan2
- SPATA31D1 | c.174T>C p.N58= | Silent (SNP) | VAF 5/9 reads (56%) | called by muse, mutect2, varscan2
- AC109583.1 | c.-1353C>T | 5'UTR (SNP) | VAF 44/94 reads (47%) | called by muse, mutect2, varscan2
- ATP8A1 | c.*2905G>A | 3'UTR (SNP) | VAF 25/53 reads (47%) | called by muse, mutect2, varscan2
- BCL7A | chr12:122021260 C>G | 5'Flank (SNP) | VAF 58/128 reads (45%) | catalogued as COSV55846296; called by muse, mutect2, varscan2
- BCL7A | chr12:122021445 C>A | 5'Flank (SNP) | VAF 53/102 reads (52%) | catalogued as rs537306086, COSV55846302, COSV55847851, COSV55851309; called by muse, mutect2, varscan2
- CLEC4M | c.784+79G>A | Intron (SNP) | VAF 23/40 reads (58%) | called by muse, mutect2, varscan2
- CMSS1 | c.154-584G>C | Intron (SNP) | VAF 11/320 reads (3%) | called by muse, mutect2
- CPLX1 | c.*1468G>A | 3'UTR (SNP) | VAF 26/48 reads (54%) | called by muse, mutect2, varscan2
- CYP4X1 | c.*95G>T | 3'UTR (SNP) | VAF 16/41 reads (39%) | called by muse, mutect2, varscan2
- DDX19A | c.*649A>G | 3'UTR (SNP) | VAF 84/179 reads (47%) | catalogued as rs1282991118; called by muse, mutect2, varscan2
- DERL1 | c.*435T>G | 3'UTR (SNP) | VAF 11/72 reads (15%) | called by muse, mutect2, varscan2
- DST | c.21592-10T>G | Intron (SNP) | VAF 18/45 reads (40%) | called by muse, mutect2, varscan2
- EGFR | c.1881-203A>C | Intron (SNP) | VAF 22/48 reads (46%) | called by muse, mutect2, varscan2
- ENPEP | c.*3015G>T | 3'UTR (SNP) | VAF 32/39 reads (82%) | called by muse, mutect2, varscan2
- ERBB2 | c.-107C>T | 5'UTR (SNP) | VAF 4/10 reads (40%) | called by muse, mutect2, varscan2
- EVX2 | c.*545T>C | 3'UTR (SNP) | VAF 71/181 reads (39%) | called by muse, mutect2, varscan2
- FRZB | c.*1455C>G | 3'UTR (SNP) | VAF 11/53 reads (21%) | called by muse, mutect2, varscan2
- GAB2 | c.*2215A>G | 3'UTR (SNP) | VAF 69/130 reads (53%) | catalogued as rs912461199; called by muse, mutect2, varscan2
- GALNT5 | c.*2488A>C | 3'UTR (SNP) | VAF 44/85 reads (52%) | called by muse, mutect2, varscan2
- GATA5 | c.*1069C>T | 3'UTR (SNP) | VAF 33/92 reads (36%) | called by muse, mutect2, varscan2
- HMG20B | c.941+103C>T | Intron (SNP) | VAF 25/66 reads (38%) | called by muse, mutect2, varscan2
- IFNAR1 | c.*955C>T | 3'UTR (SNP) | VAF 41/76 reads (54%) | called by muse, mutect2, varscan2
- INSIG2 | c.*1589dup | 3'UTR (INS) | VAF 33/71 reads (46%) | called by mutect2, pindel, varscan2
- KDM5A | c.*96T>C | 3'UTR (SNP) | VAF 23/50 reads (46%) | called by muse, mutect2, varscan2
- LTB | c.163-120T>C | Intron (SNP) | VAF 101/239 reads (42%) | called by muse, mutect2, varscan2
- MGAT4C | c.-35C>T | 5'UTR (SNP) | VAF 139/288 reads (48%) | called by muse, mutect2, varscan2
- MIEF1 | c.*1432T>A | 3'UTR (SNP) | VAF 28/67 reads (42%) | called by muse, mutect2, varscan2
- MPLKIP | c.*190G>A | 3'UTR (SNP) | VAF 30/65 reads (46%) | called by muse, mutect2, varscan2
- NFATC3 | c.*1965_*1985del | 3'UTR (DEL) | VAF 39/92 reads (42%) | called by mutect2, pindel, varscan2
- ORC5 | c.991-153C>G | Intron (SNP) | VAF 16/100 reads (16%) | called by muse, mutect2
- PHB2 | c.607+38T>G | Intron (SNP) | VAF 102/210 reads (49%) | called by muse, mutect2, varscan2
- PHOX2A | c.*335C>A | 3'UTR (SNP) | VAF 20/37 reads (54%) | called by muse, mutect2, varscan2
- PLEKHG5 | c.-53-86C>T | Intron (SNP) | VAF 29/61 reads (48%) | called by muse, mutect2, varscan2
- PPP1R12A | c.-21+125T>C | Intron (SNP) | VAF 18/60 reads (30%) | catalogued as rs980228530; called by muse, mutect2, varscan2
- PRKCB | c.1864-1120A>C | Intron (SNP) | VAF 39/98 reads (40%) | called by muse, mutect2, varscan2
- PRSS53 | c.243-74A>T | Intron (SNP) | VAF 6/19 reads (32%) | called by muse, mutect2
- RAB34 | c.-159-18G>A | Intron (SNP) | VAF 39/98 reads (40%) | called by muse, mutect2, varscan2
- RAP2B | c.*894_*899del | 3'UTR (DEL) | VAF 6/55 reads (11%) | catalogued as rs199578476; called by mutect2, varscan2
- RNF183 | c.-38+449G>A | Intron (SNP) | VAF 47/114 reads (41%) | called by muse, mutect2, varscan2
- SDK1 | c.*2390T>G | 3'UTR (SNP) | VAF 67/150 reads (45%) | called by muse, mutect2, varscan2
- SGIP1 | c.*994A>G | 3'UTR (SNP) | VAF 51/55 reads (93%) | called by muse, mutect2, varscan2
- SLC22A8 | c.334-101G>A | Intron (SNP) | VAF 11/96 reads (11%) | called by muse, varscan2
- SLC35B4 | c.*4972A>C | 3'UTR (SNP) | VAF 39/78 reads (50%) | called by muse, mutect2, varscan2
- SLC35F1 | c.*2568C>A | 3'UTR (SNP) | VAF 20/51 reads (39%) | catalogued as rs1220534135; called by muse, mutect2, varscan2
- SLC4A8 | c.*501T>A | 3'UTR (SNP) | VAF 36/89 reads (40%) | called by muse, mutect2, varscan2
- SLC9A2 | c.*429dup | 3'UTR (INS) | VAF 36/105 reads (34%) | called by mutect2, pindel, varscan2
- SPAG8 | c.*826-425G>A | Intron (SNP) | VAF 8/89 reads (9%) | called by muse, mutect2
- ST8SIA1 | c.*45G>T | 3'UTR (SNP) | VAF 90/203 reads (44%) | called by muse, mutect2, varscan2
- ST8SIA1 | c.*44G>T | 3'UTR (SNP) | VAF 90/202 reads (45%) | called by muse, mutect2, varscan2
- TTC17 | c.2666-1865A>G | Intron (SNP) | VAF 42/90 reads (47%) | called by muse, mutect2, varscan2
- TYW1B | chr7:72831652 G>C | 5'Flank (SNP) | VAF 65/149 reads (44%) | called by muse, mutect2, varscan2
- VGLL3 | c.*8920C>T | 3'UTR (SNP) | VAF 38/91 reads (42%) | called by muse, mutect2, varscan2
- VWA8 | c.*534G>A | 3'UTR (SNP) | VAF 46/49 reads (94%) | called by muse, mutect2, varscan2
- ZNF670-ZNF695 | c.*207+14A>G | Intron (SNP) | VAF 23/47 reads (49%) | called by muse, mutect2, varscan2
